Somatic mutation profile of tumor specimen TARGET-30-PARDVT-01A (aliquot TARGET-30-PARDVT-01A-01D) from TARGET case TARGET-30-PARDVT, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.7 years (1,338 days).
Specimen TARGET-30-PARDVT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9adc52a-a1b6-44b7-988e-bfaab14acc5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARDVT-14A (Bone Marrow Normal), aliquot TARGET-30-PARDVT-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5916ed12-191c-4276-ae85-44e13d861ab3

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 4, RNA 2, Intron 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP11A | c.1141A>T p.S381C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs923365990; called by muse, mutect2
- BMP3 | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.473); catalogued as COSV51081720; called by muse, mutect2, varscan2
- CLEC1A | c.163C>A p.L55M | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.865); catalogued as COSV59532267; called by muse, mutect2, varscan2
- FAM91A1 | c.1996G>A p.A666T | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.025); catalogued as COSV58237272; called by muse, mutect2, varscan2
- HIGD1A | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV58414573, COSV58414971; called by muse, mutect2
- MACF1 | c.11244C>A p.N3748K (on ENST00000372915; = p.N1681K on NM_012090.5) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV57122922; called by muse, mutect2, varscan2
- MAGEC1 | c.2819G>T p.S940I | Missense Mutation (SNP) | VAF 64/95 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV53573541; called by muse, mutect2, varscan2
- MPRIP | c.731A>C p.K244T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV59048609; called by muse, mutect2
- NNMT | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55473889; called by muse, mutect2, varscan2
- OR51B2 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV60916319, COSV60916770; called by muse, mutect2, varscan2
- OR5AR1 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 55/319 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV57253971; called by muse, mutect2, varscan2
- OR5D14 | c.628A>C p.M210L | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV59456475; called by muse, mutect2, varscan2
- PRCP | c.938T>G p.L313W | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57288906; called by muse, mutect2, varscan2
- PRKCQ | c.2016G>T p.K672N | Missense Mutation (SNP) | VAF 86/276 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1017468413, COSV54112011; called by muse, mutect2, varscan2
- PXYLP1 | c.740G>T p.C247F | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359577702, COSV53890636; called by muse, mutect2, varscan2
- TBX22 | c.1300C>A p.L434I | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV64786134; called by muse, mutect2, varscan2
- TNIK | c.3808C>T p.R1270W | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs754276249, COSV52683398; called by muse, mutect2, varscan2
- TSC2 | c.4239G>C p.E1413D | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV51916975; called by muse, mutect2, varscan2
- ZHX3 | c.2692G>A p.G898S | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV58383711; called by muse, mutect2, varscan2
- ITGB4 | c.1761+1del | Frame Shift Del (DEL) | VAF 24/223 reads (11%) | called by mutect2, pindel, varscan2
- KRT26 | c.932_958del p.Q311_S319del | In Frame Del (DEL) | VAF 14/153 reads (9%) | called by mutect2, pindel
- ALDH1A2 | c.1047G>T p.V349= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV51082172; called by muse, mutect2, varscan2
- FAM167A | c.138C>T p.Y46= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV52703665; called by muse, mutect2, varscan2
- FCRL5 | c.183C>T p.Y61= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as COSV62514947; called by muse, mutect2, varscan2
- IQCA1 | c.1764C>A p.I588= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as COSV54502870, COSV54509090; called by muse, mutect2, varscan2
- OR3A4P | n.466C>A | RNA (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2, varscan2
- OSGIN1 | n.1313C>A | RNA (SNP) | VAF 10/76 reads (13%) | catalogued as COSV59420753; called by muse, mutect2, varscan2
- SYTL2 | c.1459+1500T>A | Intron (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
